Somatic mutation profile of tumor specimen TCGA-BQ-5887-01A (aliquot TCGA-BQ-5887-01A-11D-1961-08) from TCGA case TCGA-BQ-5887, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 54.1 years (19,747 days).
Specimen TCGA-BQ-5887-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 88c1df79-b972-446e-8b6d-27bd63026018.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BQ-5887-11A (Solid Tissue Normal), aliquot TCGA-BQ-5887-11A-01D-1961-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/52489cc7-4588-44d0-b3a0-950507f57c19

The open-access MAF lists 16 somatic variants for this specimen: 9 protein-altering or splice-affecting, 7 silent.
By variant classification: Silent 7, Missense Mutation 7, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKAP3 | c.1489C>G p.P497A | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.14); catalogued as COSV57420432; called by muse, mutect2, varscan2
- ARID2 | c.3010A>T p.S1004C | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV57614211; called by muse, mutect2, varscan2
- ARMT1 | c.806T>G p.L269W | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66179083; called by muse, mutect2, varscan2
- CARMIL3 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.015); catalogued as rs141263195; called by mutect2, varscan2
- COL28A1 | c.2575G>T p.D859Y | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV68084499; called by muse, mutect2, varscan2
- KDM3B | c.4988A>G p.Y1663C | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV58695056; called by muse, mutect2, varscan2
- ZSWIM2 | c.1436A>T p.N479I | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV54579333; called by muse, mutect2, varscan2
- RNMT | c.115dup p.S39Ffs*7 | Frame Shift Ins (INS) | VAF 24/120 reads (20%) | called by mutect2, pindel, varscan2
- USP24 | c.3972_3999del p.D1326* | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | called by mutect2, pindel
- COL28A1 | c.2574G>A p.K858= | Silent (SNP) | VAF 20/105 reads (19%) | catalogued as rs1384898819, COSV68084504; called by muse, mutect2, varscan2
- FLII | c.3024C>T p.F1008= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as rs1315351782, COSV57500601; called by muse, mutect2
- IGHG3 | c.687G>A p.T229= | Silent (SNP) | VAF 49/351 reads (14%) | catalogued as rs748726059; called by muse, mutect2, varscan2
- NANOS3 | c.375A>G p.R125= (on ENST00000397555; = p.R144= on NM_001098622.2) | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV59249886; called by muse, mutect2, varscan2
- NLRP7 | c.336G>A p.S112= | Silent (SNP) | VAF 54/230 reads (23%) | catalogued as rs766338217, COSV60173101; called by muse, mutect2, varscan2
- OR2G2 | c.127T>C p.L43= | Silent (SNP) | VAF 76/284 reads (27%) | catalogued as COSV60742231; called by muse, mutect2, varscan2
- RCHY1 | c.21A>G p.E7= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as COSV61009507; called by muse, mutect2
